Somatic mutation profile of tumor specimen ALCH-AESE-TTP1-A (aliquot ALCH-AESE-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-AESE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 44.0 years (16,065 days).
Specimen ALCH-AESE-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f7ab0e0-d96a-4cdd-a64d-f48fb7dcd654.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AESE-NB1-A (Blood Derived Normal), aliquot ALCH-AESE-NB1-A-2-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70e9ebda-d858-4895-a763-574085c59e54

The open-access MAF lists 186 somatic variants for this specimen: 120 protein-altering or splice-affecting, 38 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 38, Intron 18, Nonsense Mutation 10, 3'UTR 5, 5'UTR 3, Nonstop Mutation 2, In Frame Del 1, Frame Shift Del 1, 5'Flank 1, 3'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS16 | c.2656G>A p.G886R | Missense Mutation (SNP) | VAF 34/288 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs762566566, COSV99943595; called by muse, mutect2, varscan2
- AGAP2 | c.1958G>A p.R653H (on ENST00000547588 / NM_001122772.2; = p.R317H on NM_014770.4) | Missense Mutation (SNP) | VAF 50/474 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1412800570, COSV57726660; called by muse, mutect2, varscan2
- AQR | c.1255C>T p.Q419* | Nonsense Mutation (SNP) | VAF 30/250 reads (12%) | catalogued as COSV50042707; called by muse, mutect2, varscan2
- ASXL1 | c.3538G>C p.D1180H | Missense Mutation (SNP) | VAF 77/585 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.402); catalogued as rs777253679, COSV60126536; called by muse, mutect2, varscan2
- ATG9A | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as rs1352912914; called by muse, mutect2, varscan2
- C2orf16 | c.3902G>C p.R1301T | Missense Mutation (SNP) | VAF 35/315 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV62676955; called by muse, mutect2, varscan2
- CCDC97 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.222); catalogued as rs764852698; called by muse, mutect2, varscan2
- CHD4 | c.2119G>A p.D707N (on ENST00000357008 / NM_001363606.2; = p.D720N on NM_001273.5) | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.234); catalogued as COSV58894619; called by muse, mutect2, varscan2
- CNTNAP3 | c.2391C>G p.F797L | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV99904850; called by muse, varscan2
- CTNNA1 | c.94C>G p.L32V | Missense Mutation (SNP) | VAF 33/281 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV57071103, COSV57073350; called by muse, mutect2, varscan2
- CYP27B1 | c.95C>G p.S32* | Nonsense Mutation (SNP) | VAF 48/697 reads (7%) | catalogued as COSV99141568; called by muse, mutect2
- DHX32 | c.1174C>T p.L392F | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as COSV52938822; called by muse, mutect2, varscan2
- DNAH5 | c.5441C>T p.T1814I | Missense Mutation (SNP) | VAF 44/355 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV99449499; called by muse, mutect2, varscan2
- E2F5 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 63/447 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV99809356; called by muse, mutect2, varscan2
- ELOA | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as rs147397474; called by muse, mutect2, varscan2
- EPHB1 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 63/307 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.207); catalogued as rs563780078, COSV67654835, COSV67657144; called by muse, mutect2, varscan2
- EPS8L2 | c.2121G>A p.M707I | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as rs925012761; called by muse, mutect2, varscan2
- FAM155A | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 62/642 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65572073; called by muse, mutect2
- FAM90A1 | c.440G>A p.S147N | Missense Mutation (SNP) | VAF 36/644 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.205); catalogued as rs1307245442; called by muse, mutect2
- FZD7 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV53809187; called by muse, mutect2, varscan2
- KCNB2 | c.1011G>C p.L337F | Missense Mutation (SNP) | VAF 18/381 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73049977; called by muse, mutect2
- KCNN1 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.031); catalogued as rs972773573; called by muse, mutect2, varscan2
- KCNS2 | c.1108G>A p.V370I | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs751437110, COSV54640014; called by muse, mutect2, varscan2
- KRTAP12-3 | c.290G>C p.*97Sext*17 | Nonstop Mutation (SNP) | VAF 15/102 reads (15%) | catalogued as COSV59952163; called by muse, varscan2
- KY | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 51/292 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV71016932; called by muse, mutect2, varscan2
- LAMC1 | c.3428G>A p.R1143Q | Missense Mutation (SNP) | VAF 40/349 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs765333890; called by muse, mutect2, varscan2
- MEF2D | c.1442G>C p.G481A | Missense Mutation (SNP) | VAF 40/310 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.112); catalogued as COSV61726546; called by muse, mutect2, varscan2
- MKI67 | c.6454G>A p.D2152N | Missense Mutation (SNP) | VAF 51/369 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs751571262; called by muse, mutect2, varscan2
- MUC20 | c.2056C>T p.Q686* | Nonsense Mutation (SNP) | VAF 67/423 reads (16%) | catalogued as rs1036904840; called by muse, mutect2, varscan2
- NPAS4 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 70/519 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.718); catalogued as rs777027579, COSV60650844; called by muse, mutect2, varscan2
- NPC1 | c.2374A>T p.K792* | Nonsense Mutation (SNP) | VAF 49/305 reads (16%) | catalogued as CM1310281; called by muse, mutect2, varscan2
- PC | c.2395G>T p.D799Y | Missense Mutation (SNP) | VAF 50/350 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58993604; called by muse, mutect2, varscan2
- PLXNA4 | c.4729G>A p.D1577N | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762943057; called by muse, mutect2, varscan2
- PRDM9 | c.920G>C p.G307A | Missense Mutation (SNP) | VAF 64/680 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV57004209; called by muse, mutect2
- RNF216 | c.1583C>T p.T528M (on ENST00000425013 / NM_207116.3; = p.T585M on NM_207111.4) | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs144654379; called by muse, mutect2, varscan2
- SYNPO | c.2575C>T p.R859W (on ENST00000394243 / NM_001166208.2; = p.R615W on NM_007286.6) | Missense Mutation (SNP) | VAF 54/434 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs781217685; called by muse, mutect2, varscan2
- TET2 | c.3989C>G p.S1330C | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV54439573; called by muse, mutect2
- TIAM2 | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 47/413 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV100019167; called by muse, mutect2, varscan2
- TRRAP | c.3011C>T p.S1004L | Missense Mutation (SNP) | VAF 55/367 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as COSV62840542; called by muse, mutect2, varscan2
- TUT4 | c.1072G>T p.A358S | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as rs1382058835; called by muse, mutect2, varscan2
- VCAN | c.4930G>T p.E1644* | Nonsense Mutation (SNP) | VAF 28/236 reads (12%) | catalogued as COSV54111909; called by muse, mutect2, varscan2
- ZAN | c.1223G>A p.G408D | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as rs775839268; called by muse, mutect2, varscan2
- ZNF217 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 88/666 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1391146908; called by muse, mutect2, varscan2
- ZNF638 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 37/244 reads (15%) | catalogued as COSV52487755; called by muse, mutect2, varscan2
- ABCF1 | c.914A>G p.K305R (on ENST00000326195 / NM_001025091.2; = p.K267R on NM_001090.3) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.414); called by muse, mutect2
- BEX2 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 40/390 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- BICDL2 | c.730C>A p.L244M | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BMPR2 | c.2251C>T p.L751F | Missense Mutation (SNP) | VAF 38/303 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- BTBD18 | c.1780G>C p.D594H | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC171 | c.2756T>C p.V919A | Missense Mutation (SNP) | VAF 61/335 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD81 | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 107/750 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CEP350 | c.6151G>A p.E2051K | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CFAP52 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLIC6 | c.1003G>C p.E335Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.084); called by muse, varscan2
- CUL2 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.342); called by muse, mutect2
- DDX56 | c.1319A>C p.Q440P | Missense Mutation (SNP) | VAF 40/430 reads (9%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.579); called by muse, mutect2
- E2F2 | c.52G>A p.V18M | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.06); called by muse, mutect2
- FAM9B | c.561G>C p.*187Yext*4 | Nonstop Mutation (SNP) | VAF 28/196 reads (14%) | called by muse, mutect2, varscan2
- FANCB | c.1291C>G p.Q431E | Missense Mutation (SNP) | VAF 43/290 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FBXO5 | c.787T>G p.L263V | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- FREM3 | c.780_783delinsA p.N261del | In Frame Del (DEL) | VAF 15/133 reads (11%) | called by pindel, varscan2*
- FSCB | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- FSIP2 | c.18491C>G p.P6164R | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GALNT12 | c.1510G>C p.E504Q | Missense Mutation (SNP) | VAF 84/661 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- GALNT14 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- GNAI1 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- GSPT2 | c.896T>C p.I299T | Missense Mutation (SNP) | VAF 66/474 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HEATR5A | c.5655C>G p.I1885M | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- HLCS | c.1343C>A p.S448* | Nonsense Mutation (SNP) | VAF 24/368 reads (7%) | called by muse, mutect2
- IGSF3 | c.1337T>C p.V446A (on ENST00000369486 / NM_001007237.3; = p.V466A on NM_001542.4) | Missense Mutation (SNP) | VAF 62/441 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- IL13 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 29/234 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- IPO4 | c.229C>G p.R77G | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2
- KASH5 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KDM4A | c.2965G>A p.E989K | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LRBA | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.336); called by muse, varscan2
- MBNL3 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.492); called by muse, mutect2
- MET | c.3019_3028del p.F1007Ifs*19 | Frame Shift Del (DEL) | VAF 66/304 reads (22%) | called by mutect2, pindel, varscan2
- METTL8 | c.471G>C p.E157D | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.024); called by mutect2, varscan2
- MTCH1 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- MUC22 | c.1508C>T p.S503F | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- NXPH1 | c.179C>G p.S60* | Nonsense Mutation (SNP) | VAF 32/378 reads (8%) | called by muse, mutect2
- ONECUT2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 37/226 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- OR11H4 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- OR14I1 | c.270C>G p.I90M | Missense Mutation (SNP) | VAF 34/219 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PHF3 | c.4360C>T p.P1454S | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- PLCB1 | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 8/220 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); called by muse, mutect2
- PPP3CA | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, mutect2
- PROP1 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2
- PRR12 | c.388G>T p.E130* (on ENST00000615927; = p.E951* on NM_020719.3) | Nonsense Mutation (SNP) | VAF 51/308 reads (17%) | called by muse, mutect2, varscan2
- PTTG1IP | c.116-7_116-2del p.X39_splice | Splice Site (DEL) | VAF 41/391 reads (10%) | called by mutect2, pindel
- RABGAP1L | c.764C>G p.S255C | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); called by muse, varscan2
- RBPMS | c.164T>C p.I55T | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RDM1 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 31/250 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- RFX7 | c.1751C>G p.S584* (on ENST00000559447 / NM_001368074.1; = p.S681* on NM_022841.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 28/199 reads (14%) | called by muse, mutect2, varscan2
- RIMS2 | c.2093C>G p.S698C (on ENST00000666250 / NM_001348490.2; = p.S506C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/289 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPS21 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SH3D21 | c.1232A>G p.D411G (on ENST00000453908 / NM_001162530.2; = p.D300G on NM_024676.5) | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- SLC44A2 | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC9B1 | c.442G>C p.V148L | Missense Mutation (SNP) | VAF 7/201 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.088); called by muse, mutect2
- SLITRK4 | c.260C>A p.S87Y | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SON | c.3859G>A p.E1287K | Missense Mutation (SNP) | VAF 41/277 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ST7 | c.1571C>T p.S524F (on ENST00000265437 / NM_021908.3; = p.S501F on NM_018412.4) | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); called by muse, mutect2
- ST7 | c.1705G>C p.E569Q | Missense Mutation (SNP) | VAF 51/376 reads (14%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- STK33 | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STRAP | c.68G>T p.S23I | Missense Mutation (SNP) | VAF 69/447 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TESK2 | c.719T>C p.F240S | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- THAP4 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.8); called by muse, mutect2
- THAP7 | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 34/297 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TIMP4 | c.112C>G p.Q38E | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TMEM132A | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TMPO | c.1288C>G p.P430A | Missense Mutation (SNP) | VAF 29/312 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); called by muse, mutect2
- TMPO | c.1660C>G p.Q554E | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); called by muse, varscan2
- TPM1 | c.62G>C p.R21P | Missense Mutation (SNP) | VAF 89/646 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- TRIM64C | c.233G>C p.R78T | Missense Mutation (SNP) | VAF 51/482 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSBP1 | c.1005G>C p.K335N (on ENST00000617061; = p.K340N on NM_006781.5) | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTN | c.41079G>T p.W13693C (on ENST00000591111; = p.W6269C on NM_003319.4) | Missense Mutation (SNP) | VAF 20/141 reads (14%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TUBGCP6 | c.3234C>A p.N1078K | Missense Mutation (SNP) | VAF 45/354 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- VWA3A | c.2282G>A p.G761E | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ZDBF2 | c.109C>G p.Q37E | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFHX4 | c.10324G>A p.V3442I | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKS3 | c.696C>T p.L232= | Silent (SNP) | VAF 35/230 reads (15%) | catalogued as rs754095987; called by muse, mutect2, varscan2
- C15orf39 | c.1899G>A p.V633= | Silent (SNP) | VAF 29/242 reads (12%) | called by muse, mutect2, varscan2
- C6orf15 | c.597C>T p.L199= | Silent (SNP) | VAF 15/128 reads (12%) | catalogued as COSV99456546; called by muse, mutect2, varscan2
- CACNG7 | c.480C>T p.V160= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as COSV99712273; called by muse, mutect2, varscan2
- CCDC166 | c.927G>A p.Q309= | Silent (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- CHRNA6 | c.1278G>A p.S426= | Silent (SNP) | VAF 33/279 reads (12%) | catalogued as rs746178917, COSV99373082; called by muse, mutect2, varscan2
- CIART | c.627G>C p.L209= | Silent (SNP) | VAF 37/264 reads (14%) | called by muse, mutect2, varscan2
- DNAAF3 | c.639G>A p.L213= (on ENST00000524407 / NM_001256715.2; = p.L260= on NM_178837.4) | Silent (SNP) | VAF 16/149 reads (11%) | catalogued as rs895053802; called by muse, mutect2, varscan2
- EPHA7 | c.1584C>G p.P528= | Silent (SNP) | VAF 32/357 reads (9%) | catalogued as rs147962361; called by muse, mutect2
- EXOC6B | c.1647G>A p.K549= | Silent (SNP) | VAF 20/131 reads (15%) | called by muse, mutect2, varscan2
- GPR135 | c.900C>T p.I300= | Silent (SNP) | VAF 26/133 reads (20%) | catalogued as rs752583376; called by muse, mutect2, varscan2
- HECTD2 | c.1125T>C p.I375= | Silent (SNP) | VAF 41/271 reads (15%) | called by muse, mutect2, varscan2
- HSF4 | c.351G>A p.V117= | Silent (SNP) | VAF 23/184 reads (13%) | catalogued as rs770401824; called by muse, mutect2, varscan2
- IGDCC3 | c.519G>A p.E173= | Silent (SNP) | VAF 45/319 reads (14%) | called by muse, mutect2, varscan2
- ITSN2 | c.3507C>T p.I1169= | Silent (SNP) | VAF 24/236 reads (10%) | catalogued as rs749035374, COSV61944918; called by muse, mutect2, varscan2
- KMT2B | c.6498C>G p.L2166= | Silent (SNP) | VAF 18/146 reads (12%) | catalogued as rs1421196020; called by muse, mutect2, varscan2
- MELTF | c.681G>A p.V227= | Silent (SNP) | VAF 33/328 reads (10%) | called by muse, mutect2, varscan2
- MKNK1 | c.1302G>C p.R434= | Silent (SNP) | VAF 30/192 reads (16%) | catalogued as COSV57861025; called by muse, mutect2, varscan2
- MSR1 | c.12G>A p.L4= | Silent (SNP) | VAF 28/207 reads (14%) | catalogued as rs774835290; called by muse, mutect2, varscan2
- MTA1 | c.141G>C p.R47= | Silent (SNP) | VAF 31/168 reads (18%) | called by muse, mutect2, varscan2
- NEURL2 | c.501C>G p.L167= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV51943568; called by muse, mutect2, varscan2
- OFD1 | c.612G>A p.K204= | Silent (SNP) | VAF 45/314 reads (14%) | called by muse, mutect2, varscan2
- PTGER3 | c.576G>T p.P192= | Silent (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- RUNDC1 | c.810G>T p.L270= | Silent (SNP) | VAF 37/366 reads (10%) | catalogued as COSV100865778, COSV100865911; called by muse, mutect2, varscan2
- SMURF1 | c.2133G>C p.L711= | Silent (SNP) | VAF 36/410 reads (9%) | called by muse, mutect2
- SPATA31E1 | c.2676C>T p.P892= | Silent (SNP) | VAF 44/442 reads (10%) | called by muse, mutect2, varscan2
- SULT1B1 | c.702G>A p.K234= | Silent (SNP) | VAF 8/169 reads (5%) | called by muse, mutect2
- SUOX | c.1053G>A p.E351= | Silent (SNP) | VAF 42/161 reads (26%) | called by muse, mutect2, varscan2
- SYNPO | c.2718C>G p.P906= (on ENST00000394243 / NM_001166208.2; = p.P662= on NM_007286.6) | Silent (SNP) | VAF 33/249 reads (13%) | catalogued as COSV56940731; called by muse, mutect2, varscan2
- TACC2 | c.8253C>T p.L2751= (on ENST00000334433; = p.L829= on NM_006997.4) | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as COSV53285090; called by muse, mutect2, varscan2
- THAP12 | c.2079G>A p.E693= | Silent (SNP) | VAF 23/202 reads (11%) | called by muse, mutect2, varscan2
- TMTC1 | c.1350G>T p.L450= (on ENST00000539277 / NM_001193451.2; = p.L342= on NM_175861.3) | Silent (SNP) | VAF 14/259 reads (5%) | called by muse, mutect2
- TRAFD1 | c.1539G>A p.V513= | Silent (SNP) | VAF 25/229 reads (11%) | called by muse, mutect2, varscan2
- TRIM37 | c.255C>T p.T85= | Silent (SNP) | VAF 87/401 reads (22%) | called by muse, mutect2, varscan2
- TTN | c.100836G>A p.V33612= (on ENST00000591111; = p.V26188= on NM_003319.4) | Silent (SNP) | VAF 38/257 reads (15%) | called by muse, mutect2, varscan2
- VAT1 | c.18G>A p.E6= | Silent (SNP) | VAF 21/290 reads (7%) | catalogued as rs1020956035, COSV63039932; called by muse, mutect2
- ZBTB38 | c.1066C>T p.L356= | Silent (SNP) | VAF 40/238 reads (17%) | called by muse, mutect2, varscan2
- ZNF281 | c.831G>A p.R277= | Silent (SNP) | VAF 87/685 reads (13%) | called by muse, mutect2, varscan2
- ABRAXAS1 | c.178+1954G>A | Intron (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2
- ACACB | c.*2C>T | 3'UTR (SNP) | VAF 24/85 reads (28%) | catalogued as rs201813488, COSV100623422; called by muse, mutect2, varscan2
- ADIRF | c.*196C>T | 3'UTR (SNP) | VAF 46/323 reads (14%) | called by muse, mutect2, varscan2
- AP000944.5 | c.1647+9442G>A | Intron (SNP) | VAF 24/171 reads (14%) | called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57620976 G>C | 3'Flank (SNP) | VAF 42/519 reads (8%) | called by muse, mutect2
- ATP2B3 | c.3342+4557C>T | Intron (SNP) | VAF 45/414 reads (11%) | catalogued as rs1169255629, COSV99684039; called by muse, mutect2, varscan2
- BTF3 | c.-1G>A | 5'UTR (SNP) | VAF 15/88 reads (17%) | called by mutect2, varscan2
- CCDC14 | c.373+101G>C | Intron (SNP) | VAF 34/179 reads (19%) | catalogued as COSV100113239, COSV59945118; called by muse, mutect2, varscan2
- DNPEP | c.-8G>C | 5'UTR (SNP) | VAF 19/97 reads (20%) | called by muse, mutect2, varscan2
- FDFT1 | chr8:11801973 G>A | 5'Flank (SNP) | VAF 66/384 reads (17%) | called by muse, mutect2, varscan2
- GABRA6 | c.530-49G>C | Intron (SNP) | VAF 18/226 reads (8%) | called by muse, mutect2
- ICAM5 | c.-28C>G | 5'UTR (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2, varscan2
- LIPH | c.49+5485C>G | Intron (SNP) | VAF 25/178 reads (14%) | called by muse, mutect2, varscan2
- MAGED1 | c.1845-52G>C | Intron (SNP) | VAF 19/236 reads (8%) | called by muse, mutect2
- MYO9A | c.5142+636C>G | Intron (SNP) | VAF 24/204 reads (12%) | catalogued as rs1191010976; called by muse, mutect2, varscan2
- NFE2L1 | c.511-1259C>T | Intron (SNP) | VAF 9/34 reads (26%) | catalogued as rs1305969380; called by muse, mutect2, varscan2
- PAXIP1 | c.*78C>T | 3'UTR (SNP) | VAF 30/342 reads (9%) | called by muse, mutect2
- PCNX4 | c.3268-293G>A | Intron (SNP) | VAF 30/187 reads (16%) | called by muse, mutect2, varscan2
- PELP1 | c.1068+73G>C | Intron (SNP) | VAF 80/617 reads (13%) | called by muse, mutect2, varscan2
- POLR1C | c.383-12C>T | Intron (SNP) | VAF 87/439 reads (20%) | called by muse, mutect2, varscan2
- PPP1R7 | c.*566C>G | 3'UTR (SNP) | VAF 36/230 reads (16%) | called by muse, mutect2, varscan2
- PPP4R3B | c.198+82C>G | Intron (SNP) | VAF 14/154 reads (9%) | called by muse, mutect2
- RNFT2 | c.*3247G>C | 3'UTR (SNP) | VAF 53/254 reads (21%) | called by muse, mutect2, varscan2
- RSAD1 | c.841-26C>G | Intron (SNP) | VAF 91/504 reads (18%) | called by muse, mutect2, varscan2
- SHB | c.838+572C>T | Intron (SNP) | VAF 28/305 reads (9%) | catalogued as rs1316390558; called by muse, mutect2
- SHISA6 | c.799+115905G>A | Intron (SNP) | VAF 19/149 reads (13%) | called by muse, mutect2, varscan2
- SPTBN1 | c.148+32224G>A | Intron (SNP) | VAF 26/166 reads (16%) | catalogued as rs922069931; called by muse, mutect2, varscan2
- TAOK2 | c.656-95G>T | Intron (SNP) | VAF 14/127 reads (11%) | called by muse, mutect2, varscan2
